Gene-level copy-number profile of tumor specimen TCGA-EK-A2RO-01A from TCGA case TCGA-EK-A2RO, project TCGA-CESC (Cervical Squamous Cell Carcinoma and Endocervical Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, large cell, nonkeratinizing, NOS; Tissue or organ of origin: Cervix uteri; FIGO stage: Stage IIB; Tumor grade: G1; Age at diagnosis: 59.8 years (21,844 days).
Specimen TCGA-EK-A2RO-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-CESC.9aa3c042-d4d8-49d1-b72b-6b0a8ef6f432.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-EK-A2RO-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 804 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/da8d1e11-cddc-42e4-8c24-f05a90370c61

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 1: 2,313; copy number 2: 45,884; copy number 3: 5,999; copy number 4: 5,611; copy number 5: 12.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-EK-A2RO-01A-11D-A18H-01): tumor purity 0.71, ploidy 2.22, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 12 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr8:40,519,565–41,309,473, 9 genes, copy number 5: AC010857.1, ZMAT4, AC048387.1, RNU6-356P, SFRP1, MIR548AO, RPS29P2, AC104393.1, RNU6-895P.
- chr17:959,034–1,003,671, 2 genes, copy number 5: AC036164.1, TIMM22.
- chr17:1,022,476–1,022,559, 1 gene, copy number 5: MIR3183.

Autosomal genes at a single copy (total copy number 1): 2,313. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
